MMRF case MMRF_1490 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2fdff68c-7fcb-4c6e-8342-ec598f32c386

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.0 years (24,481 days); ISS stage: I; Days to last known disease status: 1,296 days (3.5 years); Days to last follow up: 1,296 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 325 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 7 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 483 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days.
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 514 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 0): M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 68.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 54.6 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 304 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 10.1 g/dL; Glucose 4.84 mmol/L.
- Day 71 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 46.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 8 g/dL; Glucose 3.74 mmol/L.
- Day 141 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 19.6 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.55 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 4.46 mmol/L.
- Day 239 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 14.3 g/L; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 8.18 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 3.96 mmol/L.
- Day 323 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.83 µg/mL; Hemoglobin 8.99 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 7.1 g/dL; Glucose 6.05 mmol/L.
- Day 463 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 5.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.27 mg/dL; Immunoglobulin G 21.7 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 548 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 15.9 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 207 ×10⁹/L.
- Day 658 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.62 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 301 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.9 mmol/L.
- Day 764 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.07 mg/dL; Immunoglobulin G 14.4 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 6.38 mmol/L.
- Day 847 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.55 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 1.78 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL.
- Day 981: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.87 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.9 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 8.31 mmol/L.
- Day 1,296 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L.

Other clinical attributes
- Day -8: Weight: 82 kg; Height: 151 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Child.

Biospecimens (1 sample)
- Sample MMRF_1490_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
